TARGET case TARGET-10-PARCVT — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/238d6b98-246f-5a7c-b627-c94de3ac8e18

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 14 years; Vital status: Dead; Days to death: 237 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 14.8 years (5,419 days); Year of diagnosis: 2007; Days to last follow up: 237 days.
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 99 days; Days to first event: 99 days; First event: Relapse.
- Days to follow up: 237 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2007.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 121 ×10³/µL.
- Day 8: Bone Marrow blast count 67%; Minimal Residual Disease (Flow Cytometry) 7.83%.
- Day 15: Bone Marrow blast count 1%.
- Day 29: Bone Marrow blast count 1%; Minimal Residual Disease (Flow Cytometry) 0.8%.

Biospecimens (2 samples)
- Sample TARGET-10-PARCVT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARCVT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_Blast_Data_20230727.xlsx, for sample TARGET-10-PARCVT-09A-01D:
- Blast %: >70

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Validation_20230727.xlsx:
- Overall Survival Time in Days: 237
- WBC at Diagnosis: 121.1
- CNS Status at Diagnosis: CNS 1
- MRD Day 8: 7.83
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0.8
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 67
- BMA Blasts Day 15: 1
- BMA Blasts Day 29: 1
- Karyotype: 26,X,+X,+14,+21[14]/46,XX[6]
- Down Syndrome: No
- DNA Index: 0.53
- Cell of Origin: B Cell ALL
